MP2PRT case MP2PRT-PAPAYV — Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia (MP2PRT-ALL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/822880d5-8662-4054-8ad4-51521d5be0d6

Demographics
Sex at birth: female; Country of residence at enrollment: United States; Age at index: 6 years; Year of birth: 1999; Vital status: Alive.

Diagnoses (1)
1. Common precursor B ALL: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 6.7 years (2,448 days); Year of diagnosis: 2005; Days to last follow up: 4,028 days (11.0 years).
   Treatment given: Initial disease status: Initial Diagnosis; Regimen or line of therapy: SR-Low Group - LRS arm:  Standard Consolidation, Standard Interim Maintenance, Standard Delayed Inte; Days to treatment start: 1 day; Days to treatment end: 800 days (2.2 years); Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 4,028 days (11.0 years); Disease response: Complete Response; Progression or recurrence: No; Days progression-free: 4,028 days (11.0 years).

Molecular and laboratory tests
- ABL1 (FISH): Negative.
- BCR (FISH): Negative.
- ETV6 (FISH): Negative.
- RUNX1 (FISH): Negative.

Biospecimens (2 samples)
- Sample MP2PRT-PAPAYV-NM1-A: Sample type: Blood Derived Cancer - Bone Marrow, Post-treatment; Tissue type: Normal; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
- Sample MP2PRT-PAPAYV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
